Surgical pathology report (de-identified scan), TCGA case TCGA-85-8354, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8354-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

[REDACTED]		
[REDACTED] ID	Gross Description	Microscopic Description
[REDACTED]		

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 5 x 5 x 5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/4 positive for metastasis (Regional 0/4) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- lower

[page 3 of 3]
OpenClinica ID	Excision Date	Laterality
		Right-lower

Source: NCI Genomic Data Commons file b6b0e5e3-a14b-4bea-8bae-8718554a348c (TCGA-85-8354.577D1D2A-E784-49EB-8A00-E28EA210DB4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).